Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6351, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6351-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. PROSTATE

TCGA - G9 - 6351

SPECIMEN(S):

A. PROSTATE

GROSS DESCRIPTION:

A. PROSTATE

Received fresh labeled with the patient identification and designated as "Part A, Prostate" is a 34g resected 4.5cm from right to left, 4.0cm from anterior to posterior, and 3.2cm from apex to base, with attached right and left seminal vesicles and vas deferens. The capsule is tan pink smooth and intact. The specimen is inked as follows: Anterior-Orange, Posterior-Black, Apex-Red, Base-Blue, Right-Green, Left-Yellow. After removal of the apex and base, the remaining prostate weight is 15g. The specimen is serially sectioned from apex to base to reveal firm tan fibrous parenchyma. No obvious lesions or nodules are grossly identified. The attached right and left seminal vesicles are 3.0 x 1.0 x 1.0cm and 4.5 x 1.0 x 1.0cm, respectively, are sectioned to beige tan cystic tissue with no gross evidence of tumor involvement. The attached right and left segments of vas deferens are 0.6 x 0.5cm and 4.0 x 0.6cm, respectively, are sectioned to reveal firm tan tubular structure with no gross evidence of tumor involvement. A portion of the specimen is submitted for tissue procurement (Levels I and III). The remainder of the specimen is submitted as follows:

A1: right apex
A2: left apex
A3: Level I right anterior capsule
A4: Level I right posterior capsule
A5: Level I left anterior capsule
A6: Level I left posterior capsule
A7: Level II right anterior
A8-A9: Level II right posterior
A10: Level II left anterior
A11-A12: Level II left posterior
A13: Level III right anterior capsule
A14: Level III right posterior capsule
A15: Level III left anterior capsule
A16: Level III left posterior capsule
A17: right base with periurethral margin
A18: left base with periurethral margin
A19: right lateral base
A20: left lateral base
A21: right base
A22: left base
A23: right seminal vesicle and vas deferens
A24: left seminal vesicle and vas deferens

DIAGNOSIS:

A. PROSTATE, PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA, GLEASON SCORE 3+4 (7/10) INVOLVING BOTH LEFT AND RIGHT LOBES OF PROSTATE AND AN ESTIMATED 10 TO 15% OF PROSTATIC GLAND
- ADENOCARCINOMA FOCALLY PRESENT AT LEFT POSTERIOR CAPSULE
- PERINEURAL INVASION IDENTIFIED
- NO EXTRAPROSTATIC EXTENSION IDENTIFIED
- BILATERAL SEMINAL VESICLE, NEGATIVE FOR TUMOR

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: PROSTATE

Location: Left

Right

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma

[page 2 of 2]
[REDACTED]

Multicentricity: Yes
Gland Involvement: 10%
Gleason Grade/Sum:: Grade 3 + 4 , Sum 7
High Grade PIN Present: Yes
Perineural Invasion: Yes
Vascular/Lymphatic Invasion: No
Seminal Vesicle Invasion: No
Periprostatic Fat Involved: No
Bladder Neck Involved: No
Margins Involvement: Yes
Location: left posterior capsule just proximal to the apex
Linear Distance: Focal (1-10mm)
Frozen Performed: No
Post Hormonal Therapy Change: No
Lymph Nodes: No lymph nodes sampled
Other Pathologic Findings: BPH
Pathological Staging (pTNM): T 2c N X M X

CLINICAL HISTORY:

None provided.

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer.

ADDENDUM:

The positive margin in this case (slide A6) was reviewed with Dr. and correlated with the gross examination and operative report. During the operative procedure there was a surgical violation of the prostatic capsule in two places that were marked by surgical sutures for gross examination. One of these areas was at the site of the positive margin and comparing this information to the histological section it is likely that inked drained through this surgically created cleft. In summary, it is likely that the tumor present at the inked surface in this slide is not a true positive margin.

[REDACTED]

Source: NCI Genomic Data Commons file 494e201b-461b-4131-a577-6c704316333f (TCGA-G9-6351.7942304B-0A3D-492C-BBB2-65695F1958E4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).